Somatic mutation profile of tumor specimen C3N-02785-01 (aliquot CPT0206110009) from CPTAC case C3N-02785, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.3 years (25,301 days).
Specimen C3N-02785-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad3e7619-e72d-45cd-9905-cd461559256d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02785-71 (Blood Derived Normal), aliquot CPT0206170002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a56f61a6-8fe7-4044-966b-6224c11d0992

The open-access MAF lists 68 somatic variants for this specimen: 47 protein-altering or splice-affecting, 15 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 15, Nonsense Mutation 5, Intron 2, 3'UTR 2, Frame Shift Del 1, 5'UTR 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 6451/6995 reads (92%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ART1 | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 34/128 reads (27%) | catalogued as rs764813601; called by muse, mutect2, varscan2
- BPIFB4 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 171/332 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs150164177; called by muse, mutect2, varscan2
- CHST9 | c.1190A>G p.D397G | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760162019; called by muse, mutect2, varscan2
- CPNE6 | c.758C>G p.T253R | Missense Mutation (SNP) | VAF 173/362 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as COSV53744396; called by muse, mutect2, varscan2
- CYTH1 | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.886); catalogued as rs771352076; called by muse, mutect2, varscan2
- FBN3 | c.2259dup p.G754Rfs*69 | Frame Shift Ins (INS) | VAF 46/115 reads (40%) | catalogued as rs755836480; called by mutect2, varscan2
- FNDC1 | c.4198G>A p.V1400M | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.084); catalogued as rs771563105, COSV51947049; called by muse, mutect2, varscan2
- GGA3 | c.1967T>C p.L656S (on ENST00000537686 / NM_138619.4; = p.L623S on NM_014001.5) | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1191043943, COSV55457746; called by muse, mutect2, varscan2
- KIF16B | c.2153A>G p.N718S | Missense Mutation (SNP) | VAF 82/305 reads (27%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs1291722195; called by muse, mutect2, varscan2
- KLHL6 | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs1489826660; called by muse, mutect2, varscan2
- KRTAP13-4 | c.236C>T p.T79M | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.315); catalogued as rs756080347; called by muse, mutect2, varscan2
- KRTAP4-16 | c.517G>C p.V173L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated, low confidence (0.61); catalogued as rs543735212; called by muse, varscan2
- LCE3E | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 181/488 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.796); catalogued as rs533619446, COSV64231813; called by muse, mutect2, varscan2
- MEGF8 | c.2276G>A p.R759H | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as rs1465559937, COSV99234402; called by muse, mutect2, varscan2
- MUC5B | c.1579G>A p.V527M | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.851); catalogued as rs754250371; called by muse, mutect2, varscan2
- NGFR | c.1078C>T p.R360W | Missense Mutation (SNP) | VAF 106/302 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.729); catalogued as rs752053070, COSV50803523; called by muse, mutect2, varscan2
- NR1D1 | c.1063C>G p.L355V | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.101); catalogued as rs930720343; called by muse, mutect2, varscan2
- OR11G2 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 78/171 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs760576322, COSV62132780; called by muse, mutect2, varscan2
- ORM1 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 298/675 reads (44%) | catalogued as rs776100400, COSV99035321; called by mutect2, varscan2
- PCDHA4 | c.1802C>T p.S601L | Missense Mutation (SNP) | VAF 178/473 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV100793157, COSV63538698, COSV63546855; called by muse, mutect2, varscan2
- PHF20L1 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.685); catalogued as rs1399603982, COSV55188552; called by muse, varscan2
- RGPD8 | c.3422C>T p.A1141V | Missense Mutation (SNP) | VAF 86/721 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs779217394; called by muse, mutect2, varscan2
- RYR1 | c.4006C>T p.R1336C | Missense Mutation (SNP) | VAF 188/562 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV62097377; called by muse, mutect2, varscan2
- SHISA9 | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 94/358 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs1382105608, COSV69644859; called by muse, mutect2, varscan2
- SHPRH | c.2386C>T p.R796W | Missense Mutation (SNP) | VAF 106/283 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs765062036, COSV51612664; called by muse, mutect2, varscan2
- TBC1D30 | c.2197C>T p.R733* (on ENST00000542120; = p.R570* on NM_015279.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 134/377 reads (36%) | catalogued as rs1427958132; called by muse, mutect2, varscan2
- ABCC10 | c.3526C>G p.Q1176E (on ENST00000372530 / NM_001198934.2; = p.Q1148E on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- ACVR1 | c.1223G>C p.G408A | Missense Mutation (SNP) | VAF 66/234 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ARRB1 | c.425T>A p.V142E | Missense Mutation (SNP) | VAF 118/282 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASIC2 | c.1157A>T p.Y386F | Missense Mutation (SNP) | VAF 80/209 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CASKIN2 | c.3586C>T p.Q1196* | Nonsense Mutation (SNP) | VAF 101/293 reads (34%) | called by muse, mutect2, varscan2
- CYP3A7 | c.985C>T p.Q329* | Nonsense Mutation (SNP) | VAF 88/253 reads (35%) | called by muse, mutect2, varscan2
- ITGB6 | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNJ3 | c.1245del p.K415Nfs*3 | Frame Shift Del (DEL) | VAF 33/92 reads (36%) | called by mutect2, pindel, varscan2
- MAGEB16 | c.129T>A p.H43Q | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT tolerated (0.28); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MTR | c.2503C>T p.P835S | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRX | c.2729C>G p.A910G | Missense Mutation (SNP) | VAF 301/802 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- RPS6KB1 | c.703A>G p.T235A | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SYNRG | c.3493G>A p.A1165T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, varscan2
- SYT17 | c.97A>G p.K33E | Missense Mutation (SNP) | VAF 83/275 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TAS2R39 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 43/252 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TBC1D4 | c.3508A>G p.K1170E | Missense Mutation (SNP) | VAF 78/152 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- UBR4 | c.8866G>A p.G2956R | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- USP17L1 | c.1399C>T p.H467Y | Missense Mutation (SNP) | VAF 94/336 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- ZBTB16 | c.487A>G p.S163G | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- ZNF687 | c.2619G>C p.M873I | Missense Mutation (SNP) | VAF 92/246 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- CTAGE1 | c.1164C>T p.D388= | Silent (SNP) | VAF 57/124 reads (46%) | catalogued as rs773483618, COSV66942802; called by muse, mutect2, varscan2
- GMIP | c.960G>A p.A320= | Silent (SNP) | VAF 78/211 reads (37%) | called by muse, mutect2, varscan2
- GRHL2 | c.1687C>T p.L563= | Silent (SNP) | VAF 319/610 reads (52%) | called by muse, mutect2, varscan2
- HOXC12 | c.378G>A p.P126= | Silent (SNP) | VAF 35/73 reads (48%) | called by muse, mutect2, varscan2
- IGHA2 | c.219G>A p.P73= | Silent (SNP) | VAF 135/533 reads (25%) | catalogued as rs781958889; called by muse, mutect2, varscan2
- IL3RA | c.9C>T p.L3= | Silent (SNP) | VAF 100/265 reads (38%) | catalogued as rs768766086, COSV100452249; called by muse, mutect2, varscan2
- KRT32 | c.264C>T p.S88= | Silent (SNP) | VAF 154/410 reads (38%) | catalogued as rs755257444, COSV56788652; called by muse, mutect2, varscan2
- MON2 | c.2061G>A p.A687= | Silent (SNP) | VAF 36/98 reads (37%) | catalogued as rs772419939, COSV54806129; called by muse, mutect2, varscan2
- NPTX2 | c.1152C>T p.R384= | Silent (SNP) | VAF 50/250 reads (20%) | catalogued as rs748698114, COSV55716163; called by muse, mutect2, varscan2
- NTSR1 | c.267G>A p.A89= | Silent (SNP) | VAF 306/577 reads (53%) | catalogued as COSV65138018; called by muse, mutect2, varscan2
- PDE10A | c.1755C>G p.L585= | Silent (SNP) | VAF 103/317 reads (32%) | called by muse, mutect2, varscan2
- RAD51AP2 | c.2773T>C p.L925= | Silent (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- SLC16A4 | c.246C>T p.D82= | Silent (SNP) | VAF 40/96 reads (42%) | catalogued as rs776399818; called by muse, mutect2, varscan2
- TAAR9 | c.417C>T p.T139= | Silent (SNP) | VAF 21/34 reads (62%) | called by muse, mutect2, varscan2
- ZNF831 | c.1728C>T p.G576= | Silent (SNP) | VAF 110/208 reads (53%) | catalogued as rs770491483, COSV64043046; called by muse, mutect2, varscan2
- LGSN | c.-17A>G | 5'UTR (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- PEG10 | c.*852C>T | 3'UTR (SNP) | VAF 55/278 reads (20%) | called by muse, mutect2, varscan2
- REEP6 | c.*498G>A | 3'UTR (SNP) | VAF 84/261 reads (32%) | catalogued as rs541407733; called by muse, varscan2
- RN7SL759P | chr15:20570821 G>A | 5'Flank (SNP) | VAF 196/1104 reads (18%) | catalogued as rs1257292037; called by muse, mutect2, varscan2
- TEKT4 | c.499-627C>A | Intron (SNP) | VAF 117/350 reads (33%) | catalogued as rs556402371; called by muse, mutect2, varscan2
- TSPAN32 | c.628-20C>T | Intron (SNP) | VAF 29/120 reads (24%) | catalogued as rs577127602; called by muse, mutect2
